CCDI case PBCJSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/0b66de44-e4c0-48f5-8035-ef15d35d3825

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.2 years (5,926 days).

Biospecimens (3 samples)
- Sample 0DTLGA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTLGF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTLGM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
